TARGET case TARGET-10-PARUNW — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b9d6d5c6-1fcc-480f-9e72-83f8b5a47053

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 1 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 1.4 years (503 days); Year of diagnosis: 2008; Days to last follow up: 2,790 days (7.6 years).
   Treatment given: Protocol identifier: AALL0232.

Follow-up (2 entries)
- Days to follow up: 977 days (2.7 years); Days to first event: 977 days (2.7 years); First event: Relapse.
- Days to follow up: 2,790 days (7.6 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 277 ×10³/µL.
- Day 8: Minimal Residual Disease (Flow Cytometry) 0.14%.

Biospecimens (3 samples)
- Samples TARGET-10-PARUNW-09A, TARGET-10-PARUNW-09B (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARUNW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Dicentric_20230727.xlsx (sheet Clinical Data):
- First Event: Relapse (off-therapy)
- Overall Survival Time in Days: 2790
- WBC at Diagnosis: 277
- CNS Status at Diagnosis: CNS 2
- MRD Day 8: 0.14
- MRD Day 8 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- Karyotype: 45,XX,dic(9;20)(p11;q11)[17]/46,XX[3]
- DNA Index: 1
- Cell of Origin: B-Precursor
